Gene-level copy-number profile of tumor specimen TCGA-02-0060-01A from TCGA case TCGA-02-0060, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.1 years (24,151 days).
Specimen TCGA-02-0060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9da48e30-aca5-4d70-b538-cc6412a3dc5d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0060-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3f81a7e-1742-4179-b35f-38e571ed54c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,355; copy number 3: 2,520; copy number 4: 48,973; copy number 5: 4,113; copy number 7: 108; copy number 11: 90; copy number 14: 141; copy number 17: 156; copy number 20: 166; copy number 25: 125; copy number 28: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0060-01): tumor purity 0.78, ploidy 2, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 728 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes, copy number 11: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 11: TRGV5P, TRGV5, TRGV4.
- chr12:44,498,616–49,527,425, 164 genes, copy number 11–17 (within-gene range 3–17) (broad region; genes not listed).
- chr12:54,276,631–54,345,083, 1 gene, copy number 20 (within-gene range 3–20): AC078778.1.
- chr12:54,301,202–78,213,010, 545 genes, copy number 11–28 (within-gene range 3–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
